Somatic mutation profile of tumor specimen 0DO7MI from CCDI case PBCCJG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.9 years (1,419 days).
Specimen 0DO7MI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cbb446a-326b-4ce0-b4a2-a4477d699893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO7LZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1f64881-6fda-492e-90c6-f62d7911b499

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 216/692 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 22/718 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- CLEC4M | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 316/916 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs371058590; called by muse, mutect2
- MS4A1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 366/1110 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs201665706, COSV100619431; called by muse, mutect2, varscan2
- PIK3R1 | c.1378_1380del p.S460del (on ENST00000521381 / NM_181523.3; = p.S190del on NM_181504.4) | In Frame Del (DEL) | VAF 292/894 reads (33%) | catalogued as COSV57137095; called by mutect2, varscan2
- SIPA1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 188/488 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.749); catalogued as rs1192267096; called by muse, mutect2, varscan2
- PCLO | c.9259G>A p.G3087S | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ASXL3 | c.2154G>A p.P718= | Silent (SNP) | VAF 553/1411 reads (39%) | catalogued as rs370185733, COSV52471685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D32 | c.891A>G p.E297= | Silent (SNP) | VAF 290/805 reads (36%) | catalogued as rs772202404; called by muse, mutect2, varscan2
- DDC | c.944+2443C>T | Intron (SNP) | VAF 183/478 reads (38%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+43256G>A | Intron (SNP) | VAF 173/428 reads (40%) | called by muse, mutect2, varscan2
- TCL1B | c.*15+19C>T | Intron (SNP) | VAF 103/290 reads (36%) | catalogued as rs771726123; called by muse, mutect2, varscan2
